TCGA case TCGA-33-4538 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c70a5975-c37b-47cc-9113-427a754807d8

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 2,979 days (8.2 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,174 days); Year of diagnosis: 2002; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: RX; Days to last follow up: 2,979 days (8.2 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.
- ECOG performance status: 2; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 2,979.

Other clinical attributes
- DLCO (% of predicted): 20; FEV1/FVC before bronchodilator (%): 3; FEV1 before bronchodilator (% of reference): 2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 51.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-33-4538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-33-4538-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-33-4538-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-33-4538-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-33-4538-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.8; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received neo-adjuvant treatment prior to resection of TCGA tumor per enrollment form.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,979 days; disease-specific survival: event status not recorded, 2,979 days; disease-free interval: no event (censored), 2,979 days; progression-free interval: no event (censored), 2,979 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-33-4538-01A-01D-1195-01): tumor purity 0.59, ploidy 3.06, whole-genome doublings 1.
